Somatic mutation profile of tumor specimen TARGET-10-PARAGW-09A (aliquot TARGET-10-PARAGW-09A-01D) from TARGET case TARGET-10-PARAGW, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.8 years (1,378 days).
Specimen TARGET-10-PARAGW-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f516ee1e-ebb4-4bed-9381-788893af5d4a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARAGW-10A (Blood Derived Normal), aliquot TARGET-10-PARAGW-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b86e08a4-0afd-4f40-a904-b9f01a130e9c

The open-access MAF lists 10 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 3, Intron 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SRRM2 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 46/93 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs372559298; called by muse, mutect2, varscan2
- ZNF516 | c.1918G>A p.G640S | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs559748313, COSV71586733; called by muse, mutect2, varscan2
- NEU1 | c.993C>G p.F331L | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- OR2F2 | c.262G>C p.E88Q | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- HAUS6 | c.2700C>T p.I900= | Silent (SNP) | VAF 9/175 reads (5%) | catalogued as rs1376467075; called by muse, mutect2
- KCNT2 | c.681G>A p.L227= | Silent (SNP) | VAF 66/134 reads (49%) | called by muse, mutect2, varscan2
- LRRC66 | c.1398C>T p.H466= | Silent (SNP) | VAF 59/128 reads (46%) | catalogued as rs371327332; called by muse, mutect2, varscan2
- CALD1 | c.72-8043C>G | Intron (SNP) | VAF 49/108 reads (45%) | called by muse, mutect2, varscan2
- COA8 | c.123+87A>G | Intron (SNP) | VAF 4/44 reads (9%) | catalogued as rs1025049835; called by muse, mutect2
- TAP1 | c.*104G>T | 3'UTR (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2
